Somatic mutation profile of tumor specimen 0DETFK from CCDI case PBBREU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Sertoli cell tumor, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 17.6 years (6,412 days).
Specimen 0DETFK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dbeda40-6229-4e1c-a3ff-0cf70b775e10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DETFH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a513ef4b-31da-4b06-95c8-668a66d5050f

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 136/840 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKN2 | c.1437T>G p.F479L | Missense Mutation (SNP) | VAF 31/966 reads (3%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.97); catalogued as COSV100281882; called by muse, mutect2
- ZNF865 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.06); catalogued as rs1415653776; called by muse, mutect2, varscan2
- CNOT3 | c.1200C>T p.G400= | Silent (SNP) | VAF 53/389 reads (14%) | catalogued as rs373169471; called by muse, mutect2, varscan2
